Somatic mutation profile of tumor specimen ALCH-B4AC-TTP1-A (aliquot ALCH-B4AC-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4AC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.6 years (21,056 days).
Specimen ALCH-B4AC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e03e1b4-834c-4df7-b234-f8b657d04a57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4AC-NB1-A (Blood Derived Normal), aliquot ALCH-B4AC-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afb0ddc3-c3bf-4238-9ad4-08b66ce49550

The open-access MAF lists 381 somatic variants for this specimen: 253 protein-altering or splice-affecting, 79 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 79, Intron 19, Nonsense Mutation 17, Frame Shift Del 15, RNA 12, 3'UTR 7, 5'UTR 5, 5'Flank 5, Splice Site 4, Frame Shift Ins 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs367850319, CM003242; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CYBB | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as rs1556470794, CM980478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.6502G>T p.E2168* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as rs779739455, COSV58918164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.69G>C p.P23= | Splice Region (SNP) | VAF 14/341 reads (4%) | catalogued as COSV99788304; called by muse, mutect2
- ACKR3 | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56021794, COSV56024119; called by muse, mutect2, varscan2
- ADAMTS2 | c.3415C>A p.P1139T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV52366704, COSV52392661; called by muse, mutect2, varscan2
- ADGRD1 | c.1355A>G p.Q452R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs769376342; called by mutect2, varscan2
- APBA2 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1440356258; called by muse, mutect2, varscan2
- BMS1 | c.1873A>G p.S625G | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV65734247; called by muse, mutect2, varscan2
- CACFD1 | c.195-1G>T p.X65_splice | Splice Site (SNP) | VAF 41/163 reads (25%) | catalogued as COSV99390265; called by muse, mutect2, varscan2
- CBFA2T3 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | catalogued as COSV51922710; called by muse, mutect2, varscan2
- CCDC40 | c.2268C>G p.I756M | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs1277374938; called by muse, mutect2
- CCL21 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1322924992; called by muse, mutect2, varscan2
- CCR2 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52749972; called by muse, mutect2, varscan2
- CDC42BPB | c.3252G>C p.R1084S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs774836834; called by muse, mutect2, varscan2
- CDH10 | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.989); catalogued as COSV100053421; called by muse, varscan2
- CDH10 | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.318); catalogued as rs137998365, COSV52574951; called by muse, mutect2, varscan2
- CDH11 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51755925; called by muse, mutect2, varscan2
- CNGB3 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs762689312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT6L | c.1490A>T p.H497L (on ENST00000504123 / NM_001286790.2; = p.H492L on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1224253268; called by mutect2, varscan2
- CPE | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV68579815, COSV68580216; called by muse, mutect2, varscan2
- CTNNA2 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs199898826; called by muse, mutect2, varscan2
- CTNND2 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1448038278; called by muse, mutect2, varscan2
- DGKB | c.2350C>A p.P784T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV51759473; called by muse, varscan2
- DMBT1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV57537712; called by muse, mutect2
- DPRX | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV64949752; called by muse, mutect2, varscan2
- EDEM1 | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs866197564, COSV99849544; called by muse, mutect2
- ESR1 | c.942G>T p.Q314H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99239706; called by muse, mutect2
- EXOSC5 | c.391G>C p.A131P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99652749; called by muse, mutect2, varscan2
- EYS | c.4702C>T p.R1568C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1332331626, COSV58202459; called by muse, mutect2, varscan2
- FGG | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.052); catalogued as COSV100272066; called by muse, mutect2
- GABRB2 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99197934; called by muse, mutect2
- GFPT2 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as COSV99517154; called by muse, mutect2
- GOLGA8M | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.319); catalogued as rs570327391; called by muse, varscan2
- GPAT2 | c.1545C>G p.H515Q | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.899); catalogued as COSV100853307; called by muse, mutect2, varscan2
- GZF1 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs766222115; called by muse, mutect2, varscan2
- IFNL2 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs753803573; called by muse, mutect2, varscan2
- IGSF1 | c.3785T>C p.I1262T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1176829403; called by muse, mutect2, varscan2
- IL12RB2 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52026104; called by muse, mutect2, varscan2
- INPP4A | c.2725G>C p.E909Q (on ENST00000074304 / NM_001134224.1; = p.E870Q on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50810680, COSV50820631; called by muse, mutect2
- IRS2 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.14); catalogued as rs771982742; called by muse, mutect2, varscan2
- KHDC1L | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV64893268; called by muse, mutect2, varscan2
- KRTAP26-1 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs371533379; called by muse, mutect2, varscan2
- L3MBTL3 | c.230dup p.S78Efs*44 | Frame Shift Ins (INS) | VAF 15/151 reads (10%) | catalogued as rs767328555; called by mutect2, pindel
- LRFN5 | c.767G>T p.R256I | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99982671; called by muse, mutect2, varscan2
- LRRC24 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.265); catalogued as COSV52880664; called by muse, mutect2, varscan2
- LRRC66 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs748311910; called by muse, mutect2, varscan2
- MBD5 | c.2007G>T p.L669F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs140060547; called by muse, mutect2, varscan2
- MFSD11 | c.681T>C p.F227= | Splice Region (SNP) | VAF 20/164 reads (12%) | catalogued as rs1390721420; called by muse, mutect2, varscan2
- MRTFA | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1261744978; called by muse, mutect2
- MSRA | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs748972988; called by muse, mutect2, varscan2
- MYO3A | c.4708C>A p.Q1570K | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as COSV99780607; called by muse, mutect2, varscan2
- NCKAP1L | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as rs140186453, COSV53204699; called by muse, mutect2
- NIBAN1 | c.2201C>G p.T734R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.377); catalogued as COSV100836639; called by muse, mutect2, varscan2
- NKX2-6 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs1563305195; called by muse, mutect2, varscan2
- OCA2 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs369322694, COSV100668206; called by muse, mutect2, varscan2
- OR2M4 | c.166del p.H56Tfs*26 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as COSV60708296; called by mutect2, pindel, varscan2
- OR4M1 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as COSV60062372; called by muse, mutect2
- OR5D14 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV59455942; called by muse, mutect2, varscan2
- OR5H6 | c.146T>C p.V49A (on ENST00000642105; = p.V33A on NM_001005479.2) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs1477680373; called by muse, mutect2
- OR7C2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as rs760423088; called by muse, mutect2, varscan2
- OTOS | c.144G>T p.W48C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757799035, COSV100108940, COSV56228932; called by muse, mutect2, varscan2
- OXTR | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301038975; called by muse, varscan2
- PAM | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV57216982; called by muse, mutect2, varscan2
- PCDHGA1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.037); catalogued as rs1406713856, COSV65300108; called by muse, mutect2, varscan2
- PDZRN4 | c.2775G>T p.M925I (on ENST00000402685 / NM_001164595.2; = p.M667I on NM_013377.4) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV100114092, COSV54212910; called by muse, mutect2, varscan2
- PKHD1 | c.1762C>A p.L588I | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV61894568; called by muse, mutect2, varscan2
- PLA2G4C | c.290A>T p.D97V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs147316960; called by mutect2, varscan2
- PLAG1 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.039); catalogued as COSV57611293; called by muse, mutect2, varscan2
- PLCL2 | c.1829A>T p.K610M (on ENST00000615277 / NM_001144382.2; = p.K484M on NM_015184.5) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV67622315; called by muse, mutect2, varscan2
- PLSCR5 | c.497C>G p.T166R | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.161); catalogued as COSV71649018; called by muse, mutect2
- PREPL | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99576203; called by muse, mutect2, varscan2
- RAI14 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV54291334; called by muse, mutect2
- RAPGEF4 | c.1316G>C p.R439P | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51415926, COSV99911480; called by muse, mutect2, varscan2
- RBP3 | c.2189T>C p.I730T | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1053679537; called by muse, mutect2, varscan2
- REG3G | c.168G>C p.L56F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV55451085; called by muse, mutect2, varscan2
- RNF17 | c.1553T>C p.V518A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV99692021; called by muse, mutect2, varscan2
- RPH3A | c.1340G>A p.R447H (on ENST00000389385 / NM_001143854.2; = p.R443H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368853756; called by muse, mutect2, varscan2
- RYR2 | c.7961A>G p.Q2654R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV63660493; called by mutect2, varscan2
- SBF2 | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56298344; called by muse, mutect2
- SCN9A | c.5408_5409del p.S1803* (on ENST00000303354; = p.S1792* on NM_002977.3) | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | catalogued as rs945489250; called by pindel, varscan2
- SIM1 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs754625496, COSV53491160; called by muse, mutect2, varscan2
- SPATA7 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as COSV99248289; called by muse, mutect2, varscan2
- SYNE2 | c.19634A>G p.N6545S | Missense Mutation (SNP) | VAF 33/352 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs201715228; called by muse, mutect2
- TFPT | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as rs1394523441; called by muse, mutect2, varscan2
- TIMM13 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1356395012; called by muse, mutect2
- TMEM249 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1479498059, COSV100095513; called by muse, mutect2
- TMTC1 | c.1383G>C p.Q461H (on ENST00000539277 / NM_001193451.2; = p.Q353H on NM_175861.3) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55492309; called by mutect2, varscan2
- TP53 | c.230del p.P77Qfs*46 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as COSV53581107; called by mutect2, pindel, varscan2
- TTN | c.11353G>T p.E3785* (on ENST00000591111; = p.E3739* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/192 reads (4%) | catalogued as COSV59936781; called by muse, mutect2
- TTN | c.2684G>A p.G895D (on ENST00000591111; = p.G849D on NM_003319.4) | Missense Mutation (SNP) | VAF 24/152 reads (16%) | PolyPhen benign (0); catalogued as rs745555109; called by muse, varscan2
- TULP1 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV57692073; called by muse, mutect2, varscan2
- UPP1 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs773869355; called by muse, mutect2, varscan2
- VWDE | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as rs1367069122; called by muse, mutect2, varscan2
- ZEB2 | c.17T>C p.M6T | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV57963319; called by muse, mutect2
- ZNF35 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV56075773; called by muse, mutect2, varscan2
- ZNF41 | c.2072A>G p.Y691C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs777060943, COSV57443427; called by muse, mutect2, varscan2
- ZNF479 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV100482586, COSV58639502; called by muse, mutect2, varscan2
- ZNF777 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56097714; called by muse, mutect2, varscan2
- ZNF804A | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56459285; called by muse, mutect2, varscan2
- ZSCAN2 | c.1546del p.Q516Sfs*3 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | catalogued as COSV57571999; called by mutect2, pindel, varscan2
- A4GNT | c.674del p.P225Lfs*3 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- ABCB1 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCC2 | c.2098A>G p.T700A | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2
- ABHD12B | c.926T>C p.L309S (on ENST00000337334 / NM_001206673.2; = p.L232S on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABHD13 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AC013489.1 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- AC090517.4 | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ACIN1 | c.103T>A p.F35I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADAM9 | c.2265_2278del p.H756Dfs*56 | Frame Shift Del (DEL) | VAF 28/204 reads (14%) | called by mutect2, pindel
- ADAMTS19 | c.3253G>C p.A1085P | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ADCY10 | c.2461A>G p.S821G | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2
- ALMS1 | c.3479C>T p.P1160L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALS2 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ANK2 | c.1435G>T p.V479L | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ANO4 | c.2295dup p.D766Rfs*10 (on ENST00000392977 / NM_001286615.2; = p.D731Rfs*10 on NM_178826.4) | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.1867G>T p.E623* (on ENST00000393797 / NM_001319850.2; = p.E604* on NM_032496.4) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- ATXN3L | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- BTAF1 | c.5051G>T p.G1684V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CDA | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH10 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDH11 | c.2337dup p.K780* | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel
- CDH18 | c.350A>T p.D117V | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDKN2A | c.170_180del p.A57Gfs*59 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2*
- CDR1 | c.297G>C p.L99F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRM2 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CHRM2 | c.1320T>A p.Y440* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- COG1 | c.193A>T p.T65S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- COL9A1 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- COX7A1 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CSMD1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP3A5 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- DDC | c.1180C>A p.Q394K | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH10 | c.3691C>A p.H1231N (on ENST00000409039; = p.H1170N on NM_207437.3) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- E2F4 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELOA2 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by mutect2, varscan2
- F13B | c.164T>C p.L55S | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM114A1 | c.538G>C p.G180R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBN2 | c.2550T>G p.C850W | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLT1 | c.1603T>C p.C535R | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA4 | c.722-1G>T p.X241_splice | Splice Site (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- GAD1 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GCNT4 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- GJC1 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLIPR1 | c.90T>A p.N30K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- GRIP1 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2
- GRM1 | c.278del p.P93Rfs*35 | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | called by mutect2, pindel, varscan2
- GRM8 | c.1711C>A p.L571I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GUCY1A2 | c.1774A>G p.M592V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by mutect2, varscan2
- HAUS4 | c.465+5G>T | Splice Region (SNP) | VAF 26/185 reads (14%) | called by muse, mutect2, varscan2
- HEATR6 | c.1384A>G p.M462V | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HOXD11 | c.709del p.A237Qfs*55 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- IL1RL1 | c.470C>A p.S157* | Nonsense Mutation (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- IL37 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA8 | c.1732C>A p.H578N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- JADE1 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2
- KIF18B | c.1687G>T p.G563W (on ENST00000593135 / NM_001265577.2; = p.G575W on NM_001264573.2) | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- KRT3 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LGR4 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- LPIN2 | c.1451C>A p.S484* | Nonsense Mutation (SNP) | VAF 55/290 reads (19%) | called by muse, mutect2, varscan2
- LRRC7 | c.2035G>T p.E679* (on ENST00000651989 / NM_001370785.2; = p.E646* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- LRRC9 | c.3901C>A p.L1301I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MAGEC3 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- MAN1A1 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K19 | c.3776A>G p.E1259G | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP7 | c.1632G>T p.E544D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2
- MUC13 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- MUC16 | c.14378G>A p.S4793N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); called by mutect2, varscan2
- MYO1G | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- NBPF11 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NDUFS4 | c.183_191del p.T63_T65del | In Frame Del (DEL) | VAF 16/139 reads (12%) | called by mutect2, pindel, varscan2
- NEFL | c.1250A>T p.Q417L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NES | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NGEF | c.1699C>G p.R567G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); called by muse, mutect2
- NIN | c.2701T>C p.Y901H | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by muse, mutect2
- NINL | c.356A>T p.D119V | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- NOVA1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NPHS1 | c.3470C>G p.S1157C | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- NPLOC4 | c.1191T>A p.D397E | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10Q1 | c.153G>T p.W51C | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR11H2 | c.535G>T p.D179Y (on ENST00000556246; = p.D190Y on NM_001197287.1) | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OR12D3 | c.169A>T p.M57L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- OR2L3 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- OR2T12 | c.467T>A p.L156Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, varscan2
- OR2T12 | c.417C>A p.C139* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | called by muse, varscan2
- OR51E2 | c.50C>G p.P17R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- OR5L1 | c.751T>A p.F251I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- OR8K3 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OTOG | c.2364del p.C789Afs*26 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- PAK1 | c.289A>C p.T97P | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PAPPA2 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAQR9 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PARP8 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- PCLO | c.1385A>T p.Q462L | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PCNT | c.5053A>T p.M1685L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE1C | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PEAR1 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHF2 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- PLA2G2A | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCG2 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- PLEC | c.5608G>C p.E1870Q (on ENST00000322810 / NM_201380.4; = p.E1760Q on NM_000445.5) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLEKHA5 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLIN1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA4 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by mutect2, varscan2
- PPIC | c.510+1G>T p.X170_splice | Splice Site (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- PPP1R21 | c.1317A>T p.K439N | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- PRDM9 | c.705del p.N236Tfs*11 | Frame Shift Del (DEL) | VAF 14/162 reads (9%) | called by mutect2, pindel
- PSIP1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PSRC1 | c.806C>A p.A269E (on ENST00000409138 / NM_001363309.1; = p.A239E on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- PTPRQ | c.3577G>A p.E1193K (on ENST00000616559; = p.E1151K on NM_001145026.2) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2
- QPCTL | c.686A>T p.K229M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- RAG1 | c.2296A>G p.N766D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RALGPS2 | c.289T>G p.F97V | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RASGRP2 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RBBP8NL | c.696C>G p.C232W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RBPMS | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RCAN2 | c.491T>A p.V164E | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS2 | c.4769C>G p.S1590C (on ENST00000666250 / NM_001348490.2; = p.S1161C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SCN8A | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- SCNN1A | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SERTAD2 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SLC14A2 | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC24A5 | c.661A>T p.N221Y | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SLC44A5 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SLC4A10 | c.1538T>A p.F513Y (on ENST00000446997 / NM_001354461.2; = p.F483Y on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SLITRK2 | c.2136C>A p.Y712* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- SNX7 | c.966G>T p.K322N | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SORCS1 | c.1534A>T p.R512W | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SORCS1 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SORL1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPICE1 | c.229T>C p.W77R | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- STXBP5L | c.653del p.P218Qfs*8 | Frame Shift Del (DEL) | VAF 14/137 reads (10%) | called by mutect2, pindel, varscan2
- STXBP5L | c.2018T>A p.L673Q | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SYN1 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SYT10 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- TBX18 | c.544C>G p.H182D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.984); called by muse, mutect2
- TENT5D | c.549G>T p.M183I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by mutect2, varscan2
- TERF1 | c.583del p.E195Kfs*22 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- TF | c.269A>T p.Y90F | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2
- TTC14 | c.1984del p.E662Nfs*5 | Frame Shift Del (DEL) | VAF 69/314 reads (22%) | called by mutect2, pindel, varscan2
- UBE3A | c.248G>C p.C83S | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- UBR5 | c.7481A>T p.D2494V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- UGT1A10 | c.60dup p.G21Wfs*34 | Frame Shift Ins (INS) | VAF 11/81 reads (14%) | called by mutect2, pindel
- UNC79 | c.5972C>A p.P1991H (on ENST00000393151 / NM_001346218.2; = p.P1814H on NM_020818.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UQCRH | c.244-2A>T p.X82_splice | Splice Site (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
- UROD | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- USP24 | c.7003C>T p.R2335* | Nonsense Mutation (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- VWDE | c.2213A>G p.H738R | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- YME1L1 | c.1298G>A p.C433Y (on ENST00000326799 / NM_139312.3; = p.C376Y on NM_014263.4) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF267 | c.2097T>A p.Y699* | Nonsense Mutation (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2, varscan2
- ZNF268 | c.1985A>G p.H662R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF536 | c.2834del p.P945Lfs*3 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- ZNF852 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- ADAM15 | c.1527C>T p.G509= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as rs750901317, COSV55126187; called by muse, mutect2
- AK8 | c.267G>A p.E89= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV53752896; called by muse, mutect2, varscan2
- ANKRD30B | c.2796A>G p.E932= | Silent (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- AQP4 | c.426G>T p.V142= | Silent (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2
- ARFIP2 | c.213A>G p.P71= | Silent (SNP) | VAF 40/195 reads (21%) | catalogued as rs758308260; called by muse, mutect2, varscan2
- ATP7B | c.3567T>C p.C1189= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as rs773148537; called by muse, mutect2, varscan2
- ATRAID | c.804C>T p.S268= (on ENST00000611786; = p.S155= on NM_016085.5) | Silent (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- BBS4 | c.357T>C p.A119= | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- BRI3BP | c.543G>C p.P181= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- BRPF3 | c.2277G>A p.R759= | Silent (SNP) | VAF 45/135 reads (33%) | called by muse, mutect2, varscan2
- CDC73 | c.750T>C p.F250= | Silent (SNP) | VAF 19/176 reads (11%) | catalogued as COSV66466650; called by muse, mutect2, varscan2
- COL11A1 | c.2817T>A p.P939= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- COL15A1 | c.54G>T p.S18= | Silent (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- COL24A1 | c.5104C>A p.R1702= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- COL4A3 | c.915T>G p.P305= | Silent (SNP) | VAF 23/343 reads (7%) | catalogued as COSV67414196; called by muse, mutect2
- DENND2A | c.669A>G p.E223= | Silent (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- DOCK4 | c.3924C>T p.D1308= | Silent (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- EBF1 | c.120C>T p.N40= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2
- ENPP3 | c.495T>C p.S165= | Silent (SNP) | VAF 17/232 reads (7%) | called by muse, mutect2
- EPB41L3 | c.2598G>T p.A866= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV59470904; called by muse, mutect2, varscan2
- EZR | c.309C>T p.F103= | Silent (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- F5 | c.2985G>A p.Q995= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV63125689; called by muse, mutect2
- FBXW11 | c.873T>C p.R291= | Silent (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- GRPR | c.201A>G p.T67= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1208411119; called by muse, mutect2, varscan2
- H2AC11 | c.237C>T p.I79= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs753021077; called by muse, mutect2, varscan2
- HTR1B | c.588G>T p.V196= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2
- IARS1 | c.18A>C p.P6= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- ING2 | c.501A>T p.A167= | Silent (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- ITIH2 | c.1731C>A p.P577= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV64434097; called by muse, mutect2
- KATNIP | c.1689G>T p.L563= | Silent (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- KCNH8 | c.2274G>T p.S758= | Silent (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- KLHL23 | c.657C>G p.L219= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs1413528256, COSV55870127; called by muse, mutect2
- LPO | c.579G>T p.R193= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV51862369; called by mutect2, varscan2
- LRRC4B | c.366G>A p.V122= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- MAP7D2 | c.288A>C p.R96= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV101107421; called by muse, mutect2, varscan2
- MUC16 | c.3711A>T p.P1237= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- MYH13 | c.4525C>T p.L1509= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV52828295; called by muse, mutect2, varscan2
- NTN5 | c.1413C>T p.R471= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- OR2Y1 | c.186T>C p.F62= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as rs749328347; called by muse, mutect2, varscan2
- OR51I2 | c.600C>G p.L200= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as rs776056338; called by muse, mutect2, varscan2
- OR51S1 | c.414C>A p.L138= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- OR5H15 | c.327C>A p.T109= | Silent (SNP) | VAF 37/188 reads (20%) | called by muse, mutect2
- OR9G4 | c.696A>G p.S232= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV100265306; called by mutect2, varscan2
- PCDHA10 | c.1635C>A p.G545= | Silent (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.789C>A p.A263= | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.552G>A p.E184= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV53912871; called by muse, mutect2, varscan2
- PDHA1 | c.324C>T p.I108= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs865935012; called by muse, mutect2, varscan2
- PFN4 | c.285C>T p.T95= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs775430317; called by mutect2, varscan2
- PKD1L3 | c.192G>A p.K64= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- PKHD1 | c.1308C>G p.T436= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- PLBD2 | c.561G>C p.L187= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- POTEA | c.1098C>G p.G366= (on ENST00000519951 / NM_001005365.2; = p.G320= on NM_001002920.1) | Silent (SNP) | VAF 30/246 reads (12%) | called by muse, mutect2, varscan2
- PREPL | c.2079G>A p.E693= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- PRKD1 | c.822C>G p.V274= | Silent (SNP) | VAF 8/248 reads (3%) | called by muse, mutect2
- PTPN13 | c.5751C>G p.S1917= (on ENST00000411767 / NM_080683.3; = p.S1898= on NM_006264.3) | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV100365047, COSV57403337; called by muse, mutect2, varscan2
- PTPRQ | c.5145T>C p.N1715= (on ENST00000616559; = p.N1673= on NM_001145026.2) | Silent (SNP) | VAF 38/202 reads (19%) | called by muse, mutect2, varscan2
- REG3A | c.504C>G p.P168= | Silent (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- RFX4 | c.1680G>T p.T560= (on ENST00000392842 / NM_213594.3; = p.T466= on NM_032491.6) | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs779148172; called by muse, mutect2, varscan2
- RIT2 | c.303C>A p.V101= | Silent (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- RUSC1 | c.1960T>C p.L654= (on ENST00000368352 / NM_001105203.2; = p.L185= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs1365905584; called by muse, varscan2
- SLC1A6 | c.1086C>T p.Y362= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- SLC24A2 | c.1584T>A p.I528= | Silent (SNP) | VAF 42/234 reads (18%) | catalogued as COSV99647370; called by muse, mutect2, varscan2
- SLC30A5 | c.1743G>T p.A581= | Silent (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- SLC4A10 | c.1132C>T p.L378= (on ENST00000446997 / NM_001354461.2; = p.L348= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs780200992, COSV99763702; called by muse, mutect2
- SLFN14 | c.2058G>A p.A686= | Silent (SNP) | VAF 16/252 reads (6%) | catalogued as rs1181853871; called by muse, mutect2
- SORL1 | c.579C>T p.F193= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV99036286; called by muse, mutect2, varscan2
- SPI1 | c.108C>T p.Y36= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- TAF1A | c.321A>G p.L107= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs1319938353; called by muse, mutect2, varscan2
- TBC1D13 | c.690C>T p.G230= | Silent (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.1530A>G p.L510= | Silent (SNP) | VAF 50/230 reads (22%) | called by muse, mutect2, varscan2
- TBPL2 | c.813A>G p.A271= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as rs748138034; called by muse, mutect2, varscan2
- TECRL | c.156C>G p.V52= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- TRAPPC4 | c.285C>T p.S95= | Silent (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- TRAV9-1 | c.312C>A p.S104= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.27775C>T p.L9259= (on ENST00000591111; = p.L8332= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs780753483; ClinVar: likely benign; called by muse, varscan2
- UNC45B | c.216C>T p.I72= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- WDR49 | c.2013C>A p.P671= (on ENST00000308378 / NM_001366158.1; = p.P1012= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 79/308 reads (26%) | catalogued as rs145156716; called by muse, mutect2, varscan2
- XIRP2 | c.132T>C p.L44= | Silent (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- ZC3H7B | c.48C>T p.F16= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- AC024598.1 | c.1130-796G>T | Intron (SNP) | VAF 7/60 reads (12%) | catalogued as COSV60824657; called by muse, mutect2
- AC098591.2 | n.840T>A | RNA (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- BTN2A2 | c.952+16C>T | Intron (SNP) | VAF 11/262 reads (4%) | called by muse, mutect2
- C11orf40 | n.190G>C | RNA (SNP) | VAF 12/120 reads (10%) | catalogued as rs769106575, COSV56892244; called by muse, mutect2, varscan2
- CALM2 | c.-54G>C | 5'UTR (SNP) | VAF 15/104 reads (14%) | catalogued as rs202158230; called by muse, mutect2, varscan2
- CCNC | c.32+1505C>G | Intron (SNP) | VAF 37/120 reads (31%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2566C>T | 3'UTR (SNP) | VAF 10/170 reads (6%) | catalogued as rs942904686; called by muse, mutect2
- CSHL1 | c.471+103del | Intron (DEL) | VAF 27/154 reads (18%) | catalogued as COSV99367731; called by mutect2, pindel, varscan2
- DAPK1 | c.602+14C>A | Intron (SNP) | VAF 12/146 reads (8%) | catalogued as rs1318820591; called by muse, mutect2
- DOCK8 | c.53+218C>G | Intron (SNP) | VAF 12/87 reads (14%) | catalogued as COSV101213690; called by muse, mutect2, varscan2
- EPOR | c.*665C>G | 3'UTR (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- FLJ40288 | n.742C>G | RNA (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- GNAS | c.970+19C>G | Intron (SNP) | VAF 46/222 reads (21%) | called by muse, mutect2, varscan2
- GRIA2 | c.2406+445A>G | Intron (SNP) | VAF 30/137 reads (22%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.-4C>A | 5'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- HSP90AA4P | n.1654G>T | RNA (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- IGHV3-73 | c.-25C>A | 5'UTR (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- KMT5A | chr12:123384101 G>T | 5'Flank (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- MBD1 | c.*33-16A>T | Intron (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- MBD4 | c.1276+25C>T | Intron (SNP) | VAF 25/275 reads (9%) | called by muse, mutect2
- MTND6P20 | chr8:46843409 C>A | 3'Flank (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- MYADML | n.1009C>G | RNA (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- MYH16 | n.4208C>A | RNA (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- NBPF22P | n.468C>A | RNA (SNP) | VAF 15/165 reads (9%) | called by muse, mutect2
- OR11H2 | chr14:19713905 C>A | 5'Flank (SNP) | VAF 23/171 reads (13%) | called by muse, mutect2, varscan2
- OR2M1P | n.266G>C | RNA (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- OR52B1P | n.542G>T | RNA (SNP) | VAF 5/41 reads (12%) | catalogued as rs1390324613; called by muse, mutect2, varscan2
- PABPC1P2 | n.939G>T | RNA (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- PAX4 | c.*38A>G | 3'UTR (SNP) | VAF 50/124 reads (40%) | called by muse, mutect2, varscan2
- PCDH15 | c.*2G>T | 3'UTR (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2
- PHKB | c.2427+1035A>T | Intron (SNP) | VAF 32/232 reads (14%) | called by muse, mutect2, varscan2
- PIPSL | n.1867A>G | RNA (SNP) | VAF 13/153 reads (8%) | called by muse, mutect2
- POLR1H | chr6:30057445 C>T | 5'Flank (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- PRECSIT | n.890C>T | RNA (SNP) | VAF 12/72 reads (17%) | catalogued as rs1016192911; called by muse, mutect2, varscan2
- PYCR1 | c.*279C>T | 3'UTR (SNP) | VAF 92/272 reads (34%) | catalogued as rs369375273, COSV100321509; called by muse, mutect2, varscan2
- RHOA | c.156+2096A>T | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22612010 T>C | 5'Flank (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- RUFY1 | c.1512-30C>A | Intron (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- SLC4A1AP | c.1145-183G>A | Intron (SNP) | VAF 9/198 reads (5%) | catalogued as rs944267169; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-47964G>T | Intron (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- SLFN12L | c.1040-35G>C | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- SRP14 | c.25-22G>T | Intron (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*2685G>C | 3'UTR (SNP) | VAF 42/542 reads (8%) | called by muse, mutect2
- XPA | c.-14G>T | 5'UTR (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2
- ZIC4 | c.-15-1178G>T | Intron (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- ZNF236 | c.-7A>C | 5'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- ZNF341 | chr20:33731938 G>A | 5'Flank (SNP) | VAF 3/23 reads (13%) | called by muse, varscan2
- ZNF99 | c.*647C>A | 3'UTR (SNP) | VAF 10/90 reads (11%) | catalogued as COSV101233697; called by muse, varscan2
- ZSCAN32 | c.839-592C>T | Intron (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
